Surgical pathology report (de-identified scan), TCGA case TCGA-37-3792, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-3792-01A (Primary Tumor).

[page 1 of 4]
TCGA-37-3792

Index						Clinical Diagnosis
1						Lung Cancer
						Lung Cancer

[page 2 of 4]
TCGA-37-3792

Date of	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container
	Lung	Primary	Tumor	Tissue	OCT	block	1	n/a
	Blood	n/a	Normal	Blood	frozen	tube	1	n/a

[page 3 of 4]
TCGA-37-3792

Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type
n/a	surgery	Squamous cell carcinoma	2	2	0	0	none
n/a	blood draw	n/a	n/a	n/a	n/a	n/a	none

[page 4 of 4]
Component of treatment (Chemo / Horm Th Details)	Tumor cell %
n/a	over 50
n/a	n/a

Source: NCI Genomic Data Commons file fb0c600c-7573-4ead-bbc6-7412512af151 (TCGA-37-3792.D3661994-55F7-48D5-B27E-2BD64D13F4F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).